Somatic mutation profile of tumor specimen BA2072D (aliquot aq-BA2072D) from BEATAML1.0 case 2115, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Primary diagnosis: Acute myeloid leukemia, CBF-beta/MYH11; Tissue or organ of origin: Bone marrow; Age at diagnosis: 35.3 years (12,904 days).
Specimen BA2072D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be7e16cd-4900-4917-b190-d2efd2f53022.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2372D (Solid Tissue Normal), aliquot aq-BA2372D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49d218a4-ff1b-47fb-a573-7c724f3cf765

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC41A3 | c.592G>T p.A198S | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.268); called by muse, mutect2
- TBC1D20 | c.627-1G>T p.X209_splice | Splice Site (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- CCDC178 | c.2520G>T p.V840= (on ENST00000383096 / NM_001105528.3; = p.V802= on NM_198995.3) | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV55793559; called by muse, mutect2
